Somatic mutation profile of tumor specimen TCGA-O9-A75Z-01A (aliquot TCGA-O9-A75Z-01A-11D-A33Q-10) from TCGA case TCGA-O9-A75Z, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 44.3 years (16,183 days).
Specimen TCGA-O9-A75Z-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 296b8b55-5d7a-42e9-99b9-eecf193d2d96.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-O9-A75Z-10A (Blood Derived Normal), aliquot TCGA-O9-A75Z-10A-01D-A33Q-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6e9ce437-779b-4487-8f07-477e338c8d15

The open-access MAF lists 16 somatic variants for this specimen: 10 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 7, Silent 6, Frame Shift Del 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CFH | c.1021C>T p.R341C | Missense Mutation (SNP) | VAF 66/177 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.101); catalogued as rs773509771, COSV62776437; called by muse, mutect2, varscan2
- FNDC11 | c.113G>T p.W38L | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100918759; called by muse, mutect2, varscan2
- HSPA8 | c.56G>C p.G19A | Missense Mutation (SNP) | VAF 42/75 reads (56%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.434); catalogued as COSV99914244; called by muse, mutect2, varscan2
- KDM4A | c.1114G>C p.E372Q | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.031); catalogued as COSV100969389, COSV64959227; called by muse, mutect2, varscan2
- LMNB1 | c.1051G>T p.D351Y | Missense Mutation (SNP) | VAF 56/152 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.793); catalogued as COSV99745645; called by muse, mutect2, varscan2
- MYO18B | c.5943C>G p.F1981L | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.153); catalogued as COSV100122777, COSV59150948; called by muse, mutect2, varscan2
- PHB2 | c.807T>A p.N269K | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as COSV99780971; called by muse, mutect2, varscan2
- ATF7IP | c.30del p.V11Sfs*8 | Frame Shift Del (DEL) | VAF 33/93 reads (35%) | called by mutect2, pindel, varscan2
- FOXP4 | c.1122del p.S375Rfs*10 (on ENST00000307972 / NM_001012426.1; = p.S374Rfs*10 on NM_138457.3) | Frame Shift Del (DEL) | VAF 10/27 reads (37%) | called by mutect2, pindel, varscan2
- FRMD6 | c.9dup p.L4Ifs*5 | Frame Shift Ins (INS) | VAF 69/180 reads (38%) | called by mutect2, pindel, varscan2
- DNAJC11 | c.948T>C p.D316= | Silent (SNP) | VAF 24/68 reads (35%) | catalogued as COSV99601881; called by muse, mutect2, varscan2
- ERCC6 | c.4041A>G p.T1347= | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as COSV100875720, COSV63389468; called by muse, mutect2, varscan2
- HMOX1 | c.264C>T p.A88= | Silent (SNP) | VAF 36/83 reads (43%) | catalogued as COSV99330607; called by muse, mutect2, varscan2
- MT1E | c.138G>A p.Q46= | Silent (SNP) | VAF 25/64 reads (39%) | catalogued as COSV100042280; called by muse, mutect2, varscan2
- NLRC4 | c.2166T>C p.S722= | Silent (SNP) | VAF 37/89 reads (42%) | catalogued as COSV100707245; called by muse, mutect2, varscan2
- TSHZ3 | c.2016C>T p.S672= | Silent (SNP) | VAF 22/49 reads (45%) | catalogued as rs373477520, COSV53674286, COSV99551460; called by muse, mutect2, varscan2
